Somatic mutation profile of tumor specimen MP2PRT-PAPIMU-TMP1-A (aliquot MP2PRT-PAPIMU-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPIMU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,586 days).
Specimen MP2PRT-PAPIMU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf3cf2a1-44f6-44f0-b243-48de286550b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPIMU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPIMU-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/527c9ed5-66c3-48f3-a2da-5b325dd29dd0

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 87/183 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PMP2 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56267684; called by muse, mutect2, varscan2
- SDR42E1 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 158/398 reads (40%) | catalogued as rs765377203, COSV61094635; called by muse, mutect2, varscan2
- XPOT | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.824); catalogued as rs200582083; called by muse, mutect2, varscan2
- ZNF385B | c.699C>A p.N233K | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.087); catalogued as COSV100416236; called by muse, mutect2, varscan2
- HHIPL2 | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 180/425 reads (42%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NLGN4Y | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 222/584 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- QRFPR | c.913T>A p.Y305N | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- OR51G1 | c.816C>T p.R272= | Silent (SNP) | VAF 141/306 reads (46%) | catalogued as rs372747926, COSV58969349; called by muse, mutect2, varscan2
